Gene-level copy-number profile of tumor specimen TCGA-D8-A1XG-01A from TCGA case TCGA-D8-A1XG, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 86.9 years (31,748 days).
Specimen TCGA-D8-A1XG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.f2ca4584-cab5-49ef-b6b2-f2311785e403.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D8-A1XG-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7db1ddfa-b4f5-4673-8549-f9d64a4adfe8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,918; copy number 2: 51,062; copy number 3: 125; copy number 5: 2; copy number 6: 2,713.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D8-A1XG-01A-11D-A14F-01): tumor purity 0.83, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,715 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:76,074,746–77,067,546, 8 genes, copy number 6 (within-gene range 3–6): ST6GALNAC3, AC103592.1, AC104458.1, TPI1P1, RNU6-161P, LINC02567, ST6GALNAC5, MIR7156.
- chr1:88,313,153–92,184,725, 76 genes, copy number 6 (within-gene range 1–6) (broad region; genes not listed).
- chr1:95,474,737–95,782,342, 2 genes, copy number 5 (within-gene range 1–5): LINC01761, LINC02607.
- chr1:106,544,342–108,509,243, 25 genes, copy number 6: AL499605.1, AL596327.1, MTATP6P14, MTCO1P14, LINC01661, PRMT6, NTNG1, NDUFA4P1, VAV3, MIR7852, VAV3-AS1, LINC02785, SLC25A24, AL359258.2, AL359258.3, NBPF4, AL359258.1, SLC25A24P1, NBPF5P, SLC25A24P2, AL390038.1, NBPF6, AL392088.2, ST13P21, AL392088.1.
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,918. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
